MMRF case MMRF_2172 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f6fa1482-8bc2-4131-bb77-4ac38bba20d1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 596 days (1.6 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.4 years (26,456 days); ISS stage: II; Days to last known disease status: 596 days (1.6 years); Days to last follow up: 596 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 342 days; Days to treatment end: 356 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 345 days; Days to treatment end: 352 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 345 days; Days to treatment end: 431 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 461 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 555 days (1.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 446 days (1.2 years); Days to treatment end: 522 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 474 days (1.3 years); Days to treatment end: 513 days (1.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 474 days (1.3 years); Days to treatment end: 554 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 540 days (1.5 years); Days to treatment end: 555 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 540 days (1.5 years); Days to treatment end: 560 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 596.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.949 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 145 mg/dL; Immunoglobulin G 65.2 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 4.1 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 23 g/L; Total Protein 9.8 g/dL; Glucose 7.26 mmol/L.
- Day 100 (ECOG 2): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.944 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.5 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 189 (ECOG 1): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.765 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.711 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2 mmol/L; Albumin 29 g/L; Total Protein 5.3 g/dL; Glucose 4.95 mmol/L.
- Day 300 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.25 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 4.3 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 359 (ECOG 1): M Protein 1.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.5 mg/dL; Immunoglobulin G 21.9 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.96 µg/mL; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 453 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.746 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.3 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 4.33 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 7.15 mmol/L.
- Day 554 (ECOG 1): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.46 mg/dL; Immunoglobulin G 9.63 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 12.8 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 1.78 mmol/L; Albumin 23 g/L; Total Protein 4.9 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day 0: Weight: 122 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2172_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2172_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
